HCMI case HCM-BROD-1119-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/511b885f-5e6d-4d7c-a08a-8dda5d042b4e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1944; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C69.3; Tissue or organ of origin: Eye, NOS; Classification of tumor: primary; Age at diagnosis: 72.0 years (26,307 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C78.0; Tissue or organ of origin: Eye, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: metastasis; Age at diagnosis: 75.8 years (27,675 days); Days to diagnosis: 1,368 days (3.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Maintenance Therapy; Days to treatment start: 1,403 days (3.8 years); Days to treatment end: 1,633 days (4.5 years); Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 1,857 days (5.1 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 1,856.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 180 cm; BMI: 23.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples)
- Sample HCM-BROD-1119-C43-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
- Sample HCM-BROD-1119-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-1119-C43-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
